Somatic mutation profile of tumor specimen TARGET-10-PARNDY-09A (aliquot TARGET-10-PARNDY-09A-01D) from TARGET case TARGET-10-PARNDY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,338 days).
Specimen TARGET-10-PARNDY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fb26255-b38b-4acb-9e4b-76d090231ff1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNDY-10A (Blood Derived Normal), aliquot TARGET-10-PARNDY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d1f50f0-fe44-4367-a924-560da3e42295

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, 5'Flank 2, 3'UTR 1, In Frame Del 1, Intron 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.527+6G>C | Splice Region (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100047081; called by muse, mutect2, varscan2
- GPR171 | c.722T>C p.I241T | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs372656427; called by muse, mutect2, varscan2
- IGHV1-3 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs782691780; called by muse, mutect2
- ITGB8 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs139414321, COSV99750467; called by muse, mutect2, varscan2
- PCDHB11 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100697144; called by mutect2, varscan2
- TRPV4 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.99); catalogued as rs369637458; called by muse, mutect2, varscan2
- ZNF211 | c.634C>A p.P212T (on ENST00000347302 / NM_198855.4; = p.P225T on NM_006385.5) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs936386547; called by muse, mutect2, varscan2
- ZNF483 | c.1816C>A p.P606T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58515410; called by muse, mutect2
- AL031681.2 | c.3244C>A p.L1082I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2
- C1GALT1C1L | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GABRE | c.442A>T p.S148C | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GOLGA8N | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHD2-8 | chr14:105907207 TGTGGGTATA>CCCCG | Missense Mutation (DEL) | VAF 19/33 reads (58%) | called by pindel, varscan2*
- IGKV1D-13 | c.347_349del p.Y116_P117delinsS | In Frame Del (DEL) | VAF 35/54 reads (65%) | called by mutect2, pindel, varscan2
- KIF17 | c.1599G>T p.E533D | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAB21L2 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TACC2 | c.8244C>A p.D2748E (on ENST00000334433; = p.D826E on NM_006997.4) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- TRPM4 | c.1357C>A p.H453N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2
- WNT9B | c.445_446dup p.G150Rfs*25 | Frame Shift Ins (INS) | VAF 27/70 reads (39%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2455C>A p.R819= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- KCNQ5 | c.2112G>A p.A704= | Silent (SNP) | VAF 55/120 reads (46%) | catalogued as rs142867844, COSV59647840; called by muse, mutect2, varscan2
- PLD1 | c.129C>T p.D43= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs145417719; called by muse, mutect2, varscan2
- STK40 | c.1029G>T p.G343= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- TENM2 | c.4074G>A p.P1358= (on ENST00000518659 / NM_001122679.2; = p.P1119= on NM_001080428.3) | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs374089694, COSV69132154; called by muse, mutect2, varscan2
- TLN2 | c.4008C>G p.L1336= | Silent (SNP) | VAF 42/69 reads (61%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9845G>C | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as rs781967413; called by muse, mutect2, varscan2
- MRPL35 | c.*2951C>G | 3'UTR (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- MTFR1L | chr1:25820797 T>C | 5'Flank (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2
- MTFR1L | chr1:25820799 G>A | 5'Flank (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2
